Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KM, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KM-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology

Page 1 of 3

REPORT Tel:

Clinical Consultant & Location

Sex

Unit No

This Copy For:

SPECIMEN

LEFT ENUCLEATED EYE
Prognostic

CLINICAL DETAILS

Choroidal melanoma.
Tumour size: 16.6 x 15.7mm (8.9mm).

MACROSCOPIC DESCRIPTION

An intact, left eye.

Dimensions: Axial 24.8mm, Horizontal 26mm, Vertical 26mm

Cornea: Horizontal 12mm, Vertical 12mm

Optic nerve
Length 10mm, Diameter 4mm

On trans-illumination, a shadow measuring 20 x 21mm is seen posterolaterally.

Plane of section: horizontal

Intraocular description:

On opening, a black mass is seen. The tumour extends 1.6mm from the optic nerve.

Tumour size

LBD 16.8mm, Height 9mm

MICROSCOPY

Sections show a pigmented choroidal melanoma of mixed cell type in which the epithelioid cell component amounts up to 80%. Tumour cells express Melan-A and HSP 27 (score 1). The number of mitosis is approximately 2/40 high power fields. The microvasculature of the melanoma is prominent but closed loops are not present in the planes of sections. The lymphocytic infiltrate within the tumour is mild. Scattered macrophages are present. Tumour necrosis is not seen.

*ICD-O-3
Melanoma, epithelioid & spindle cell
mixed 8770/3
Site @ Choroid C69.3
JW 1/17/14*

Reported:

Pathologist:

Electronically Verified:

[page 2 of 2]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex M	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

Bruch's membrane appears intact in the sections examined. There is minimal tumour extension into inner sclera but no evidence of optic nerve or vortex veins involvement is seen. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is deep. The iris shows no significant abnormality but the ciliary body appears atrophic with hyalinisation of ciliary processes. The lens shows subcapsular degenerative changes. Retina overlying the tumour is slightly atrophic and there is peripheral cystoid degeneration.

DIAGNOSIS

Left eye, enucleation: Choroidal melanoma of mixed cell type.

SUMMARY

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	1= No closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	2/40 HPF
DIFFUSE MELANOMA	No
SPREAD	2= Intra-scleral
CLEARANCE	2= Adequate
HSP-27 POSITIVITY	1= 0-20%
LARGE DIAMETER	16.8 mm
THICKNESS	9 mm

Reported:

Pathologist:

Electronically Verified:

Primary Tumour Site Discrepancy		✓
Dual/Concurrent Primary Malignancy		✓

Source: NCI Genomic Data Commons file a25c8c50-5708-4156-a68b-1c390714ca60 (TCGA-VD-A8KM.519C82A6-289D-4DB7-B484-8FDFDA1A1B40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).